Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A71V, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A71V-01A (Primary Tumor).

Result Type: Surgical Pathology Report
Result Date:
Performed By:
Encounter Info:

Surgical Pathology Report

ICD-O-3
Carcinoma papillary
renal cell 8260/3
Site @ Kidney NOS
C64.9
Jan 8/8/13

Surgical Pathology Report

Requested By:

DIAGNOSIS:

Procedure/laterality: Right kidney, partial nephrectomy.
Histologic type: Renal cell carcinoma, papillary type, mixture of Type 1 and Type 2.
Nuclear grade (Fuhrman, 1-4): 2 of 4.
Tumor size: 1.5 cm in greatest dimension.
Tumor site: Upper pole.
Tumor focality: Unifocal.
Sarcomatoid features: Absent.
Tumor necrosis: Absent.
Microscopic tumor extension: Confined to the renal parenchyma with a dense fibrous capsule.
Surgical margins: Negative.
Lymph-vascular invasion: Absent.
Lymph nodes: Not applicable.
Pathologic findings in nonneoplastic kidney: Minimal nephrosclerosis.
Pathologic staging: pT1, NX, MX.
Biorepository sample (if applicable): Positive for viable papillary renal cell carcinoma.
Block(s) containing malignancy suitable for additional testing: A2 and A3

CLINICAL INFORMATION:
Right renal mass.

SPECIMEN(S):
A: Right renal mass

GROSS DESCRIPTION:

Performed by
A. Received fresh labeled and "right renal mass," is a piece of fatty tissue 15.3 g and 5 x 3.9 x 3 cm. On one surface is a smooth membranous surface designated Gerota's fascia. This is inked black. On the other surface there is some grossly identifiable renal parenchyma, 2.2 x 1.5 x 0.3 cm. The renal parenchymal margin is inked blue. Within the renal parenchyma approximately 0.3 from the inked margin, is a mass 1.5 x 1.5 cm. Fresh tumor is submitted for research.
Representative sections are submitted in cassettes labeled
Slows: A1-A4) Sections of renal mass and margins;
A5) mirror image of tissue corresponding to research

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed. Characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file c3ce1e50-dcfc-4409-9df0-9b8714f86056 (TCGA-SX-A71V.E74526B4-ED84-473B-8607-AB00B5319495.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).